Somatic mutation profile of tumor specimen TCGA-25-2400-01A (aliquot TCGA-25-2400-01A-01W-0799-08) from TCGA case TCGA-25-2400, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 76.1 years (27,789 days).
Specimen TCGA-25-2400-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b462237-a217-4c96-96d0-43576c1b483f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2400-10A (Blood Derived Normal), aliquot TCGA-25-2400-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3721dfc-8d61-4410-a5c0-c2194a12f4f5

The open-access MAF lists 95 somatic variants for this specimen: 74 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 19, In Frame Del 3, Splice Site 3, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1, Translation Start Site 1, 5'UTR 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 107/110 reads (97%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ZBTB18 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1553270634, COSV62396575; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3842T>C p.M1281T (on ENST00000272895 / NM_173076.3; = p.M963T on NM_015657.3) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs1179051041, COSV55953344; called by muse, mutect2, varscan2
- ADA | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 58/438 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs201944717, COSV63068756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS19 | c.2685G>C p.Q895H | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV50731376, COSV50736815, COSV50738945; called by muse, mutect2, varscan2
- ARHGAP29 | c.2374A>G p.M792V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs138781972, COSV53109940, COSV53115295; called by muse, mutect2, varscan2
- C2CD2L | c.1726T>C p.S576P | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV60884307; called by mutect2, varscan2
- CDC42EP4 | c.62A>G p.D21G | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100231834; called by muse, mutect2
- COL26A1 | c.1048G>T p.G350W (on ENST00000313669 / NM_001278563.3; = p.G348W on NM_133457.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs370309900, COSV58122278; called by muse, mutect2, varscan2
- CTPS2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs1333403911, COSV63721768; called by muse, mutect2, varscan2
- DENND4A | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs771755401, COSV71265463; called by muse, mutect2, varscan2
- DYNC1I1 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100268453, COSV61459830; called by muse, mutect2, varscan2
- EDIL3 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.947); catalogued as COSV56886580; called by muse, mutect2, varscan2
- EFNB1 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754504608, COSV52661318; called by muse, mutect2, varscan2
- FAM193A | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 83/159 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs773661135, COSV61192421; called by muse, mutect2, varscan2
- FMR1NB | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 106/313 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV63272723; called by muse, mutect2, varscan2
- FNDC1 | c.5095G>T p.D1699Y | Missense Mutation (SNP) | VAF 142/522 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99795892; called by muse, mutect2, varscan2
- FOXA3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444890389, COSV56215273; called by muse, mutect2, varscan2
- GALNT6 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.229); catalogued as COSV62541860; called by muse, mutect2, varscan2
- GJA1 | c.1080C>A p.D360E | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.748); catalogued as COSV56997374; called by muse, mutect2, varscan2
- GLRX3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58692695; called by muse, mutect2
- GRM1 | c.234G>T p.R78S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51120240; called by muse, mutect2, varscan2
- HTR1F | c.689T>A p.L230H | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV60389274; called by muse, mutect2, varscan2
- IL5RA | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs771055940, COSV56522074; called by muse, mutect2, varscan2
- KHNYN | c.1788-1G>A p.X596_splice | Splice Site (SNP) | VAF 21/626 reads (3%) | catalogued as COSV52163629, COSV99249740; called by muse, mutect2
- KIAA1549 | c.4602G>T p.K1534N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99650861; called by muse, mutect2
- KIDINS220 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 107/492 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.654); catalogued as rs770692330, COSV56753265, COSV99876367; called by muse, mutect2, varscan2
- KMT2D | c.5482G>C p.D1828H | Missense Mutation (SNP) | VAF 24/714 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); catalogued as COSV56445498; called by muse, mutect2
- LAMA3 | c.2362A>C p.I788L | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as COSV58065452; called by muse, mutect2, varscan2
- LIMS2 | c.61C>T p.R21C (on ENST00000355119 / NM_001161403.3; = p.R45C on NM_017980.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs745803442, COSV99760610; called by muse, mutect2, varscan2
- LRP1B | c.10715G>A p.C3572Y | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67199732; called by muse, mutect2, varscan2
- MADD | c.4222G>C p.V1408L | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100211939, COSV60621922; called by muse, mutect2, varscan2
- MAP3K2 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 70/372 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61293561; called by muse, varscan2
- MAP3K2 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV100789329; called by muse, varscan2
- MARK3 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 26/613 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.897); catalogued as rs370547663; called by muse, mutect2
- MGA | c.7304G>A p.R2435Q (on ENST00000219905 / NM_001164273.1; = p.R2226Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 145/216 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54951059, COSV54964414; called by muse, mutect2, varscan2
- MGAT1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | PolyPhen possibly damaging (0.818); catalogued as rs149151044; called by muse, mutect2, varscan2
- MKS1 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 19/22 reads (86%) | catalogued as COSV56595613; called by muse, mutect2, varscan2
- MTA2 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 148/388 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV53871102, COSV99603967; called by muse, mutect2, varscan2
- NAA11 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 183/413 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs747256226, COSV54515275; called by muse, mutect2, varscan2
- NFATC4 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1280950177, COSV51598591; called by muse, mutect2, varscan2
- NKG7 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as COSV52467259; called by muse, mutect2, varscan2
- NONO | c.637T>C p.F213L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV52136569; called by muse, mutect2, varscan2
- OR4C15 | c.895G>C p.V299L (on ENST00000314644; = p.V245L on NM_001001920.2) | Missense Mutation (SNP) | VAF 345/1641 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.477); catalogued as COSV58951795; called by muse, mutect2, varscan2
- OR6F1 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 22/502 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV100129221; called by muse, mutect2
- PAWR | c.618A>T p.L206F | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV100174240; called by muse, mutect2
- PKD1L1 | c.1823T>G p.V608G | Missense Mutation (SNP) | VAF 80/154 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56961201; called by muse, mutect2, varscan2
- RABGAP1L | c.2437G>C p.V813L | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.021); catalogued as COSV52284462, COSV52320080; called by muse, mutect2, varscan2
- RELN | c.9776C>G p.S3259C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV100633848, COSV58996462; called by muse, mutect2
- RPL10A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as rs138610837, COSV57689432; called by muse, mutect2, varscan2
- SAMD9L | c.4072G>T p.E1358* | Nonsense Mutation (SNP) | VAF 550/1510 reads (36%) | catalogued as COSV59080478; called by muse, mutect2, varscan2
- SCN1B | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 88/162 reads (54%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV52893768; called by muse, mutect2, varscan2
- SGCZ | c.368A>T p.N123I | Missense Mutation (SNP) | VAF 280/1105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV101169919; called by muse, mutect2, varscan2
- SKP2 | c.902-1G>C p.X301_splice | Splice Site (SNP) | VAF 29/351 reads (8%) | catalogued as COSV57041012; called by muse, mutect2
- SMARCC2 | c.1433A>T p.Q478L | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV57215588; called by muse, mutect2, varscan2
- SOS1 | c.3548C>G p.P1183R | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV67674442; called by muse, mutect2, varscan2
- SPAG7 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs1160189500, COSV52776627; called by muse, mutect2, varscan2
- STX11 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs763642990, COSV62448803; called by muse, mutect2, varscan2
- TXNDC17 | c.306T>G p.P102= | Splice Region (SNP) | VAF 30/37 reads (81%) | catalogued as COSV51513488; called by muse, mutect2, varscan2
- VRTN | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs150151126; called by muse, mutect2, varscan2
- WAS | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV64996784; called by muse, mutect2
- WNK1 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 19/591 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267509; called by muse, mutect2
- XIRP2 | c.5224C>A p.L1742I (on ENST00000628543; = p.L1917I on NM_152381.6) | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1357711443, COSV54689487; called by muse, mutect2, varscan2
- ZBTB48 | c.1191G>A p.M397I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV59839536; called by muse, varscan2
- ZFP28 | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56734577, COSV56735172; called by muse, mutect2, varscan2
- ZNF142 | c.1352A>G p.D451G (on ENST00000411696 / NM_001379660.1; = p.D251G on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV68743298; called by muse, mutect2, varscan2
- ZNF718 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68140340; called by muse, mutect2, varscan2
- ADCY9 | c.1441_1443del p.K481del | In Frame Del (DEL) | VAF 12/40 reads (30%) | called by pindel, varscan2
- HPSE2 | c.1100_1101del p.V367Gfs*2 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- IL18BP | c.167_168del p.P56Rfs*6 | Frame Shift Del (DEL) | VAF 22/107 reads (21%) | called by mutect2, pindel, varscan2
- MUC16 | c.28544_28545del p.F9515* | Frame Shift Del (DEL) | VAF 58/268 reads (22%) | called by mutect2, pindel, varscan2
- PCDH7 | c.1856_1867del p.L619_T623delinsP | In Frame Del (DEL) | VAF 14/63 reads (22%) | called by mutect2, pindel
- RBMS2 | c.36_38del p.T13del | In Frame Del (DEL) | VAF 41/369 reads (11%) | called by mutect2, varscan2
- SPRTN | c.813dup p.L272Tfs*8 | Frame Shift Ins (INS) | VAF 13/100 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.1149C>T p.I383= (on ENST00000611781; = p.I327= on NM_052997.2) | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as rs868304038, COSV100653525, COSV64606919; called by muse, mutect2, varscan2
- AP001781.2 | c.72G>A p.L24= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV52787630; called by muse, varscan2
- CMYA5 | c.9165A>G p.K3055= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as COSV71404709; called by muse, mutect2, varscan2
- CR2 | c.621C>A p.P207= | Silent (SNP) | VAF 82/340 reads (24%) | catalogued as rs573346582, COSV100889572, COSV100889648; called by mutect2, varscan2
- DACH2 | c.888T>A p.A296= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV64164523; called by muse, mutect2, varscan2
- ENPP7 | c.1164C>T p.Y388= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs141362079, COSV60385916; called by muse, mutect2, varscan2
- EPHA7 | c.1551T>A p.A517= | Silent (SNP) | VAF 22/176 reads (13%) | catalogued as COSV65179463; called by muse, mutect2, varscan2
- HDHD5 | c.1158C>T p.H386= (on ENST00000336737 / NM_033070.3; = p.H356= on NM_017829.5) | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs750544181, COSV50087476; called by muse, mutect2, varscan2
- IBTK | c.1968C>T p.N656= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs763305201, COSV60391801; called by muse, mutect2, varscan2
- MYLK3 | c.222C>A p.G74= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV67363325; called by mutect2, varscan2
- NDUFB8 | c.27G>A p.L9= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100144095, COSV100144110; called by muse, mutect2
- PLEKHG4 | c.568C>T p.L190= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV64612169; called by muse, mutect2, varscan2
- POPDC3 | c.783G>A p.R261= | Silent (SNP) | VAF 56/107 reads (52%) | catalogued as COSV54643460; called by muse, mutect2, varscan2
- PSAP | c.1146C>T p.C382= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs573095617, COSV56459905; ClinVar: uncertain significance / benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PSPN | c.96C>T p.A32= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs752033644, COSV55531795; called by mutect2, varscan2
- RABGGTB | c.987A>G p.L329= | Silent (SNP) | VAF 68/275 reads (25%) | catalogued as rs1368138491, COSV54199093; called by muse, mutect2, varscan2
- SBSN | c.1491G>T p.G497= (on ENST00000452271 / NM_001166034.2; = p.G154= on NM_198538.4) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV71733095; called by muse, mutect2, varscan2
- SCN7A | c.456T>A p.L152= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV69270178; called by muse, mutect2, varscan2
- ZNF804A | c.636C>A p.I212= | Silent (SNP) | VAF 51/305 reads (17%) | catalogued as COSV56440951, COSV56447572; called by muse, mutect2, varscan2
- CLDN17 | c.*1T>G | 3'UTR (SNP) | VAF 34/476 reads (7%) | catalogued as COSV99729213; called by muse, mutect2
- DNAJC22 | c.-2G>A | 5'UTR (SNP) | VAF 17/198 reads (9%) | catalogued as rs1471871693, COSV101222540; called by muse, mutect2
